Somatic mutation profile of tumor specimen PCProject_0054_T2_WES (aliquot PCProject_0054_T2_WES_1) from CMI case PCProject_0054, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 52.1 years (19,023 days).
Specimen PCProject_0054_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 813b09e0-60a9-4dcf-a8c8-f6ae2e8d8f97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0054_SALIVA (Saliva), aliquot PCProject_0054_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5d38bd2-0c34-455a-be1a-69a6beef8264

The open-access MAF lists 27 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 6, Silent 6, 3'UTR 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA3 | c.2306G>C p.R769P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60692736, COSV60699595; called by muse, varscan2
- GPR179 | c.3821C>A p.A1274D (on ENST00000621958; = p.A1273D on NM_001004334.4) | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs868459350; called by muse, mutect2, varscan2
- LY75 | c.3053C>G p.A1018G | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.339); catalogued as COSV99716161; called by muse, mutect2, varscan2
- RUSC2 | c.3754G>A p.E1252K | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV63429532; called by muse, mutect2, varscan2
- SLC12A2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1440016177; called by muse, mutect2, varscan2
- SUSD2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs370061442; called by muse, mutect2, varscan2
- TNS2 | c.261+8C>T | Splice Region (SNP) | VAF 28/149 reads (19%) | catalogued as rs375398578; called by muse, varscan2
- ZNF678 | c.1187G>A p.R396K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as rs1409311384; called by mutect2, varscan2
- ASCC3 | c.6178A>G p.T2060A | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, varscan2
- BAG5 | c.293T>G p.F98C | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MOGS | c.2383G>A p.V795I | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- PARD3 | c.3968C>T p.P1323L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- ACTL9 | c.1080C>T p.R360= | Silent (SNP) | VAF 33/233 reads (14%) | catalogued as rs782076219, COSV61006361; called by muse, mutect2, varscan2
- ADAD1 | c.1401G>A p.L467= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- CARNS1 | c.2025C>T p.N675= | Silent (SNP) | VAF 51/235 reads (22%) | catalogued as rs747355221, COSV57055603; called by muse, mutect2, varscan2
- CUL4B | c.192T>C p.S64= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as rs759951965, COSV60691897; called by mutect2, varscan2
- LILRA6 | c.753C>T p.Y251= | Silent (SNP) | VAF 14/488 reads (3%) | catalogued as rs370378163; called by muse, mutect2
- NOTCH3 | c.4638C>T p.R1546= | Silent (SNP) | VAF 60/382 reads (16%) | called by mutect2, varscan2
- AC024598.1 | c.1130-12469T>C | Intron (SNP) | VAF 11/82 reads (13%) | catalogued as COSV60824491; called by muse, mutect2, varscan2
- DUT | c.631+47T>A | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- EDRF1 | c.2371+161A>G | Intron (SNP) | VAF 7/59 reads (12%) | catalogued as rs1299179669; called by mutect2, varscan2
- METTL2B | c.*721A>G | 3'UTR (SNP) | VAF 20/198 reads (10%) | catalogued as rs1386784188, COSV52310130; called by muse, mutect2
- OPA1 | c.2983+131T>C | Intron (SNP) | VAF 8/54 reads (15%) | catalogued as rs990077966, COSV62483235; called by muse, varscan2
- ORC6 | c.*258A>G | 3'UTR (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- ORC6 | c.*359A>G | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- PCCB | c.373-135T>C | Intron (SNP) | VAF 10/77 reads (13%) | catalogued as rs1463198745; called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 12/100 reads (12%) | catalogued as rs910081914; called by muse, mutect2
